Somatic mutation profile of tumor specimen C3L-01739-01 (aliquot CPT0100100009) from CPTAC case C3L-01739, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 71.2 years (26,003 days).
Specimen C3L-01739-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24fbc383-77f7-42ec-9e61-a9c814eef841.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01739-31 (Blood Derived Normal), aliquot CPT0100140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e09ffbae-09da-41e6-80df-46bad7454638

The open-access MAF lists 1,619 somatic variants for this specimen: 1,127 protein-altering or splice-affecting, 287 silent, 205 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 754, Silent 287, Frame Shift Del 235, Intron 115, Nonsense Mutation 50, Frame Shift Ins 42, 3'UTR 33, In Frame Del 18, 5'UTR 18, RNA 17, Splice Region 14, 5'Flank 12.

Variants (750 of 1,619; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1933_1934del p.G645Wfs*12 | Frame Shift Del (DEL) | VAF 36/164 reads (22%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 32/305 reads (10%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHRNA1 | c.1072C>T p.R358W (on ENST00000261007 / NM_001039523.3; = p.R333W on NM_000079.4) | Missense Mutation (SNP) | VAF 166/381 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374391312, CM086805; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs121913395, COSV62699844; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 35/331 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- FLAD1 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 80/388 reads (21%) | catalogued as rs199979286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HIBCH | c.129del p.G44Vfs*6 | Frame Shift Del (DEL) | VAF 164/420 reads (39%) | catalogued as rs767597690; ClinVar: pathogenic; called by mutect2, varscan2
- IQSEC2 | c.4419del p.S1474Vfs*21 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs1569290954; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 64/420 reads (15%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 68/289 reads (24%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL4 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs756826551; called by muse, mutect2, varscan2
- AASDH | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52709257; called by muse, mutect2
- ABCA10 | c.2170A>G p.R724G | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs1334734775; called by muse, mutect2, varscan2
- ABCB11 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750904445, COSV55587560; called by muse, mutect2, varscan2
- ABCC3 | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1486774452; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs749943218; called by mutect2, varscan2
- ABL2 | c.28del p.E10Kfs*80 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as COSV62662690, COSV62668300; called by mutect2, pindel
- ACTN1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs771989409, COSV99517813; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 37/166 reads (22%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 25/229 reads (11%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS10 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54357115; called by muse, mutect2, varscan2
- ADCY7 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775397178, COSV54266376; called by muse, mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as rs772825390; called by mutect2, varscan2
- ADRB2 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561708699; called by muse, mutect2
- AEBP2 | c.762_764del p.S256del | In Frame Del (DEL) | VAF 36/284 reads (13%) | catalogued as rs1182948043; called by pindel, varscan2
- AGK | c.248del p.N83Mfs*13 | Frame Shift Del (DEL) | VAF 46/202 reads (23%) | catalogued as COSV62595111; called by pindel, varscan2
- AGPAT5 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs756652472, COSV53449451; called by muse, mutect2, varscan2
- AKAP11 | c.4238C>T p.S1413L | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV50292866; called by muse, mutect2, varscan2
- AKT2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs758767505, COSV60908520; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 34/255 reads (13%) | catalogued as rs771889973, COSV55672572; called by mutect2, varscan2
- AMY2B | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 63/306 reads (21%) | catalogued as rs757065720; called by muse, mutect2, varscan2
- ANK3 | c.12107C>T p.T4036M | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs373883428; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6131C>A p.P2044Q | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99783168; called by muse, mutect2, varscan2
- ANKLE1 | c.1082del p.P361Hfs*30 (on ENST00000394458; = p.P307Hfs*30 on NM_152363.6) | Frame Shift Del (DEL) | VAF 52/184 reads (28%) | catalogued as rs778834689; called by mutect2, pindel, varscan2
- ANKRD11 | c.7642C>A p.Q2548K | Missense Mutation (SNP) | VAF 117/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99967910; called by muse, mutect2, varscan2
- ANKRD26 | c.1340dup p.N447Kfs*5 | Frame Shift Ins (INS) | VAF 52/268 reads (19%) | catalogued as rs779946717; called by mutect2, varscan2
- AP002748.5 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 158/575 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as rs767343098; called by muse, mutect2, varscan2
- APOE | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs778425259; called by muse, mutect2, varscan2
- AR | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs761416673, CM1513577, COSV65952822; called by muse, mutect2
- AR | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868669253, COSV65953169; called by muse, mutect2, varscan2
- ARID1A | c.4541del p.T1514Rfs*13 | Frame Shift Del (DEL) | VAF 51/251 reads (20%) | catalogued as COSV61377853; called by mutect2, pindel, varscan2
- ARID3A | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as rs1568355580; called by muse, mutect2, varscan2
- ARL15 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762822538, COSV101544756, COSV72291226; called by muse, mutect2, varscan2
- ARRB1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 23/189 reads (12%) | catalogued as COSV63575290; called by muse, mutect2, varscan2
- ARRDC1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV58380636; called by muse, mutect2, varscan2
- ARSL | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs752354785, COSV66965067; ClinVar: uncertain significance; called by muse, mutect2
- ASAH2 | c.1694T>C p.M565T | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.046); catalogued as rs890105371; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs746676748; called by mutect2, varscan2
- ATF6 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs768207958; called by muse, mutect2, varscan2
- ATM | c.4611G>A p.Q1537= | Splice Region (SNP) | VAF 25/217 reads (12%) | catalogued as CD983707; called by muse, mutect2, varscan2
- ATM | c.6637A>G p.K2213E | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.14); catalogued as COSV53733773; called by muse, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs1555143544, COSV63112070; called by mutect2, pindel, varscan2
- ATN1 | c.2722del p.L908Wfs*45 | Frame Shift Del (DEL) | VAF 40/206 reads (19%) | catalogued as rs35279650; called by mutect2, varscan2
- ATP2B3 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 100/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782075864, COSV54845442, COSV99685266; called by muse, mutect2, varscan2
- ATP2C2 | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 77/336 reads (23%) | catalogued as rs377760863; called by muse, mutect2, varscan2
- ATRIP | c.1808T>C p.V603A | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs1179790239; called by muse, mutect2, varscan2
- AURKB | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs201709756, COSV60244668; called by muse, mutect2, varscan2
- AXIN1 | c.1759A>G p.N587D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs150340487; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 53/203 reads (26%) | catalogued as rs747119215; called by mutect2, varscan2
- BMP1 | c.1839del p.N614Tfs*138 (on ENST00000306385 / NM_006129.5; = p.N614Tfs*188 on NM_001199.4) | Frame Shift Del (DEL) | VAF 114/469 reads (24%) | catalogued as rs758822270; called by mutect2, pindel, varscan2
- BPIFA1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 77/342 reads (23%) | catalogued as COSV62824869; called by muse, mutect2, varscan2
- BPIFC | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55911213; called by muse, mutect2, varscan2
- BRAP | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs761635335; called by muse, mutect2, varscan2
- BRWD3 | c.1649del p.K550Rfs*81 | Frame Shift Del (DEL) | VAF 61/232 reads (26%) | catalogued as COSV64753454; called by mutect2, pindel, varscan2
- BTNL9 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs1471865441, COSV59793156; called by muse, mutect2, varscan2
- C16orf92 | c.288A>G p.S96= | Splice Region (SNP) | VAF 50/196 reads (26%) | catalogued as rs1264617208; called by muse, mutect2, varscan2
- C17orf97 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 130/710 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.709); catalogued as rs377377885; called by muse, varscan2
- C2CD4D | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.114); catalogued as rs1466057028, COSV100787632; called by muse, mutect2, varscan2
- C2orf16 | c.72dup p.I25Yfs*30 | Frame Shift Ins (INS) | VAF 54/216 reads (25%) | catalogued as rs766219691; called by mutect2, varscan2
- C4orf19 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.403); catalogued as COSV52649250; called by muse, mutect2, varscan2
- C4orf47 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV100293714; called by muse, varscan2
- C8B | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262020940; called by muse, mutect2, varscan2
- CA12 | c.432G>A p.L144= | Splice Region (SNP) | VAF 61/359 reads (17%) | catalogued as rs1293859811, COSV51606472; called by muse, mutect2, varscan2
- CACNA1C | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 34/224 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs761378545, COSV59737906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 107/423 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771568327, COSV59002242; called by muse, mutect2, varscan2
- CASR | c.2013del p.S672Qfs*28 (on ENST00000490131; = p.S749Qfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 30/169 reads (18%) | catalogued as COSV56134396; called by mutect2, pindel, varscan2
- CAV1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs772468332, COSV104417638; called by muse, mutect2, varscan2
- CCDC146 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs144226591; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC42 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746523334; called by muse, mutect2, varscan2
- CCER2 | c.514_516del p.K172del | In Frame Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs1411716702; called by mutect2, pindel, varscan2
- CCPG1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51241099; called by muse, mutect2, varscan2
- CD6 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs753975286; called by muse, mutect2, varscan2
- CECR2 | c.619C>T p.R207W (on ENST00000342247 / NM_001290047.2; = p.R44W on NM_001290046.1) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776351510, COSV52836394; called by muse, mutect2, varscan2
- CES3 | c.653del p.G218Vfs*54 | Frame Shift Del (DEL) | VAF 41/188 reads (22%) | catalogued as COSV57593378; called by mutect2, pindel, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 24/146 reads (16%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP91 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs759081002; called by muse, mutect2, varscan2
- CHD7 | c.5858C>T p.A1953V | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.32); catalogued as rs748578338, CM133770; called by muse, mutect2, varscan2
- CHFR | c.1447G>A p.A483T (on ENST00000432561 / NM_001161345.1; = p.A442T on NM_018223.2) | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs1454391193, COSV57173293; called by muse, mutect2, varscan2
- CHMP2A | c.340_343del p.N114Dfs*3 | Frame Shift Del (DEL) | VAF 67/241 reads (28%) | catalogued as rs1273522790, COSV53396790; called by mutect2, pindel, varscan2
- CIC | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 101/343 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs1292046972, COSV50593911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIT | c.692del p.R231Pfs*16 | Frame Shift Del (DEL) | VAF 41/236 reads (17%) | catalogued as COSV55859365; called by mutect2, pindel, varscan2
- CITED2 | c.251del p.P84Rfs*63 | Frame Shift Del (DEL) | VAF 26/139 reads (19%) | catalogued as rs748689446; called by mutect2, pindel, varscan2
- CLCNKB | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs387907411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIP3 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs552087785, COSV100859380; called by muse, mutect2, varscan2
- COPA | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54099385; called by muse, mutect2, varscan2
- COQ9 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1233305170, COSV104375219; called by muse, mutect2, varscan2
- CPEB3 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as rs753852984, COSV56453579; called by muse, mutect2, varscan2
- CRB1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1204363918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRIP3 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142092139; called by muse, mutect2, varscan2
- CROCC | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs774850102, COSV100978072; called by muse, mutect2, varscan2
- CRY1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs747384061; called by muse, mutect2, varscan2
- CSMD3 | c.3158del p.N1053Tfs*39 (on ENST00000297405 / NM_001363185.1; = p.N949Tfs*39 on NM_052900.3) | Frame Shift Del (DEL) | VAF 52/273 reads (19%) | catalogued as rs1465694861, COSV52349441; called by mutect2, pindel, varscan2
- CSNK1A1L | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs376817335; called by muse, mutect2, varscan2
- CST7 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.019); catalogued as rs897220469; called by muse, varscan2
- CTNNAL1 | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1349960988; called by muse, mutect2, varscan2
- CTR9 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1397467879, COSV63727972; called by muse, mutect2, varscan2
- CUBN | c.4351-1G>T p.X1451_splice | Splice Site (SNP) | VAF 103/496 reads (21%) | catalogued as COSV100912592; called by muse, mutect2, varscan2
- CYP27C1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs773726442; called by muse, mutect2, varscan2
- CYP2A7 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396678060; called by muse, mutect2, varscan2
- CYP7B1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV59597716; called by muse, mutect2, varscan2
- DCAF15 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.123); catalogued as rs775309882; called by muse, mutect2, varscan2
- DCAF8L1 | c.1345del p.R449Gfs*6 | Frame Shift Del (DEL) | VAF 36/181 reads (20%) | catalogued as COSV71595377; called by mutect2, pindel, varscan2
- DCST1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs149583518; called by muse, mutect2, varscan2
- DENND1A | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.353); catalogued as rs755527233, COSV101011723; called by muse, mutect2, varscan2
- DLEC1 | c.1425del p.V476Cfs*2 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs756971918; called by mutect2, pindel
- DLGAP2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101422269; called by muse, mutect2, varscan2
- DNAH1 | c.7127G>A p.R2376H | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1218859728, COSV70228397; called by muse, mutect2
- DNAH5 | c.9521C>T p.T3174M | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757354117, COSV54229730; called by muse, varscan2
- DNAH5 | c.9505C>T p.R3169C | Missense Mutation (SNP) | VAF 110/434 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768495886; called by muse, varscan2
- DNAJB6 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1426182828; called by muse, mutect2, varscan2
- DOCK3 | c.3883C>T p.R1295W | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as rs770085171; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DSCAM | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.207); catalogued as rs756786822, COSV68023945, COSV68026680; called by muse, mutect2
- DUS2 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV62710092; called by muse, mutect2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 52/192 reads (27%) | catalogued as rs772082432; called by mutect2, varscan2
- EGF | c.2648del p.P883Lfs*67 | Frame Shift Del (DEL) | VAF 120/488 reads (25%) | catalogued as rs758373637; called by mutect2, pindel, varscan2
- EHMT2 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1431130935; called by muse, mutect2, varscan2
- ELFN1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1400883369, COSV70034741, COSV70035453; called by muse, mutect2, varscan2
- ELFN1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163244033; called by muse, mutect2
- ELOA | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs749954868; called by muse, varscan2
- ELOVL4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371760799; called by muse, mutect2, varscan2
- EMC8 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1289831645; called by muse, mutect2, varscan2
- EPHA8 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs746799254, COSV51274318; called by muse, mutect2, varscan2
- EPS8L2 | c.1412dup p.D473Gfs*30 | Frame Shift Ins (INS) | VAF 22/94 reads (23%) | catalogued as rs780857388; called by mutect2, varscan2
- ESRRG | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs141423098; called by muse, mutect2, varscan2
- EXOSC2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.249); catalogued as COSV64910728; called by muse, mutect2, varscan2
- EXPH5 | c.5783A>G p.N1928S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as COSV56199409; called by muse, mutect2, varscan2
- FAAH | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV99679989; called by muse, mutect2, varscan2
- FAM107B | c.-122-5del | Splice Region (DEL) | VAF 20/94 reads (21%) | catalogued as rs756478120; called by mutect2, varscan2
- FAM186A | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 67/357 reads (19%) | catalogued as rs529099241, COSV59250361; called by muse, mutect2, varscan2
- FAM217A | c.128_130del p.K43del | In Frame Del (DEL) | VAF 68/360 reads (19%) | catalogued as rs1156923620; called by pindel, varscan2
- FAM83F | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770937456; called by muse, mutect2, varscan2
- FASTK | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs779155034, COSV52540191; called by muse, mutect2, varscan2
- FAT3 | c.12694G>A p.V4232M | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53078476, COSV53080671; called by muse, mutect2
- FAT4 | c.4528T>C p.Y1510H | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV67898386; called by muse, mutect2
- FBN2 | c.7659del p.F2554Lfs*57 | Frame Shift Del (DEL) | VAF 76/293 reads (26%) | catalogued as rs748600284, COSV99331968; called by mutect2, pindel, varscan2
- FBXO27 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369513367; called by muse, mutect2, varscan2
- FBXO30 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 61/309 reads (20%) | catalogued as COSV52790796; called by muse, mutect2, varscan2
- FCGBP | c.10195C>T p.R3399C | Missense Mutation (SNP) | VAF 61/869 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs146863017; called by muse, mutect2
- FDPS | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as rs573382158; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 75/209 reads (36%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FERMT3 | c.1939G>T p.A647S (on ENST00000279227 / NM_178443.3; = p.A643S on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV54172411; called by muse, mutect2, varscan2
- FGFR2 | c.2307C>G p.Y769* | Nonsense Mutation (SNP) | VAF 252/613 reads (41%) | catalogued as COSV60640378, COSV60661588; called by muse, mutect2, varscan2
- FGFRL1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.901); catalogued as rs1056088891; called by muse, mutect2, varscan2
- FHL2 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs768711688; called by muse, mutect2, varscan2
- FICD | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs746814032; called by muse, mutect2, varscan2
- FLOT1 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100013496; called by muse, mutect2
- FLT1 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs372046832, COSV56729596; called by muse, mutect2, varscan2
- FNDC1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 91/511 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs776548524, COSV51943574; called by muse, mutect2, varscan2
- FOXE1 | c.145del p.L49Cfs*318 | Frame Shift Del (DEL) | VAF 51/221 reads (23%) | catalogued as COSV64300517; called by mutect2, pindel, varscan2
- FOXF1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99296318; called by muse, mutect2, varscan2
- FREM2 | c.6098C>T p.T2033M | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs143791655; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 28/197 reads (14%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FSHR | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM129349; called by muse, mutect2
- FZD3 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 100/412 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs200915090, COSV53534285; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GDF11 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1480358374, COSV57690533; called by muse, mutect2
- GFRAL | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV61231972; called by muse, mutect2, varscan2
- GGN | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53058001; called by muse, mutect2, varscan2
- GLT1D1 | c.937G>A p.V313I (on ENST00000442111 / NM_001366889.1; = p.V233I on NM_144669.3) | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs377377789; called by muse, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 27/125 reads (22%) | catalogued as rs749150409; called by mutect2, varscan2
- GNPDA2 | c.153del p.K51Nfs*2 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs764046569; called by mutect2, pindel, varscan2
- GPR180 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs772949802; called by mutect2, varscan2
- GRIA4 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.976); catalogued as rs150237011; called by muse, mutect2, varscan2
- GRM7 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs763560092, COSV63166215; called by muse, mutect2, varscan2
- GRXCR1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.613); catalogued as rs769123480, COSV67672312, COSV99063713; called by muse, mutect2, varscan2
- GSN | c.2037del p.F679Lfs*2 | Frame Shift Del (DEL) | VAF 117/510 reads (23%) | catalogued as rs763056885; called by mutect2, pindel, varscan2
- GTF3C1 | c.4996G>A p.D1666N | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236375622; called by muse, varscan2
- GUCY2F | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 53/217 reads (24%) | catalogued as rs774080062; called by muse, mutect2, varscan2
- HAVCR1 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1376698064; called by muse, varscan2
- HDAC11 | c.291dup p.V98Rfs*70 | Frame Shift Ins (INS) | VAF 30/160 reads (19%) | catalogued as rs754533859; called by mutect2, varscan2
- HDAC7 | c.545C>T p.A182V (on ENST00000427332; = p.A221V on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV50336555; called by muse, mutect2, varscan2
- HEATR5A | c.5330C>T p.S1777L | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs377132147; called by muse, mutect2, varscan2
- HECTD1 | c.2740A>G p.S914G | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1566625207; called by muse, mutect2, varscan2
- HECTD4 | c.4891C>T p.R1631* | Nonsense Mutation (SNP) | VAF 71/322 reads (22%) | catalogued as COSV66399994; called by muse, mutect2, varscan2
- HJURP | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.791); catalogued as rs1287169579; called by muse, mutect2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs767148651; called by mutect2, varscan2
- HSPG2 | c.13172C>T p.S4391L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs961325868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR1B | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as rs751879830; called by muse, mutect2
- HTR2A | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66327028; called by muse, mutect2, varscan2
- IDH3B | c.1019A>T p.Y340F | Missense Mutation (SNP) | VAF 156/632 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100249978, COSV61389083; called by muse, mutect2, varscan2
- IGF2BP1 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs769647368; called by muse, mutect2, varscan2
- IGHA1 | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 90/589 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.427); catalogued as rs762216626; called by muse, mutect2, varscan2
- IKBKB | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1363685414; called by muse, mutect2, varscan2
- IKBKE | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65624990; called by muse, mutect2, varscan2
- IMPDH1 | c.449G>A p.G150D (on ENST00000470772 / NM_001142573.2; = p.G236D on NM_000883.4) | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs745455593; called by muse, mutect2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 17/141 reads (12%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- INTS2 | c.695del p.N232Mfs*25 | Frame Shift Del (DEL) | VAF 45/177 reads (25%) | catalogued as COSV52153211; called by mutect2, pindel, varscan2
- INTS3 | c.1317C>T p.R439= | Splice Region (SNP) | VAF 45/203 reads (22%) | catalogued as rs537117097; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs771739474; called by mutect2, varscan2
- IRF4 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV66704531; called by muse, mutect2, varscan2
- IRS2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65480068; called by muse, mutect2, varscan2
- JPH2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs372515066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KANSL1L | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1222934340; called by muse, mutect2, varscan2
- KAT6A | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55905437, COSV99705834; called by muse, mutect2, varscan2
- KCNA10 | c.647del p.R216Lfs*32 | Frame Shift Del (DEL) | VAF 114/353 reads (32%) | catalogued as COSV63905147; called by mutect2, pindel, varscan2
- KCNA4 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 55/228 reads (24%) | catalogued as COSV60255201; called by muse, mutect2, varscan2
- KCNA5 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52904329; called by muse, varscan2
- KCNA5 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV52906292; called by muse, varscan2
- KCNA5 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 97/515 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV52905814; called by muse, mutect2, varscan2
- KCNC3 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.045); catalogued as COSV65386547, COSV99059355; called by muse, mutect2
- KCNK1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV64035842; called by muse, mutect2
- KCNK9 | c.1019G>A p.S340N | Missense Mutation (SNP) | VAF 148/694 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.215); catalogued as COSV100270506; called by mutect2, varscan2
- KDM5C | c.4472A>G p.E1491G | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64763701; called by muse, mutect2, varscan2
- KHK | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 117/623 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.369); catalogued as rs548115211; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 49/174 reads (28%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA2013 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs145156794; called by muse, mutect2, varscan2
- KIF21A | c.2305del p.T769Qfs*5 (on ENST00000361418 / NM_001378440.1; = p.T756Qfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/233 reads (18%) | catalogued as rs1219032396; called by mutect2, pindel, varscan2
- KIF2B | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs138252912; called by muse, mutect2, varscan2
- KIFC1 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 66/349 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373978399; called by muse, mutect2, varscan2
- KL | c.2928del p.H977Tfs*10 | Frame Shift Del (DEL) | VAF 56/259 reads (22%) | catalogued as rs1430572004, COSV66308205; called by mutect2, pindel, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 25/152 reads (16%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2D | c.13846C>A p.L4616M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1372295186; called by mutect2, varscan2
- KRT12 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1228565509, COSV52432524; called by muse, mutect2, varscan2
- KRT16 | c.197del p.G66Afs*54 | Frame Shift Del (DEL) | VAF 72/303 reads (24%) | catalogued as rs1555573913; called by mutect2, pindel, varscan2
- KRT17 | c.65dup p.G23Rfs*33 | Frame Shift Ins (INS) | VAF 57/239 reads (24%) | catalogued as rs753167272; called by mutect2, pindel, varscan2
- KRT73 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs750485971, COSV59838486; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA5 | c.7537C>T p.R2513C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs762803716; called by muse, mutect2, varscan2
- LAMA5 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs547141551; called by muse, mutect2, varscan2
- LAMB3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 124/613 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs748466087, COSV61917230; called by muse, mutect2, varscan2
- LAMC3 | c.3872G>A p.R1291Q | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs189693390; called by muse, mutect2, varscan2
- LARP1 | c.1408G>A p.V470I (on ENST00000518297 / NM_033551.3; = p.V393I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs752964192; called by muse, mutect2, varscan2
- LCOR | c.2574dup p.E859Rfs*10 | Frame Shift Ins (INS) | VAF 34/162 reads (21%) | catalogued as rs1361355752; called by mutect2, varscan2
- LDB2 | c.34_36del p.S12del | In Frame Del (DEL) | VAF 44/172 reads (26%) | catalogued as rs1322163033; called by pindel, varscan2
- LECT2 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs140811147; called by muse, mutect2, varscan2
- LGALS3BP | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1412146856; called by muse, mutect2
- LGSN | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs916438780; called by muse, mutect2
- LILRA6 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1335374079; called by muse, mutect2, varscan2
- LPIN1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766980528; ClinVar: uncertain significance; called by muse, mutect2
- LRP6 | c.2915A>G p.Y972C | Missense Mutation (SNP) | VAF 154/720 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772441071; called by muse, mutect2, varscan2
- LRRC46 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as COSV51621306; called by muse, mutect2, varscan2
- LRRIQ1 | c.1822del p.S608Qfs*2 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | catalogued as COSV101280632; called by mutect2, pindel, varscan2
- LRRIQ1 | c.2142dup p.C715Mfs*3 | Frame Shift Ins (INS) | VAF 29/153 reads (19%) | catalogued as rs774258383; called by mutect2, pindel, varscan2
- LTBP4 | c.4361C>T p.P1454L (on ENST00000308370 / NM_001042544.1; = p.P1417L on NM_003573.2) | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as rs190277382, COSV99180973; called by muse, mutect2, varscan2
- LTN1 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs752778452; called by muse, mutect2, varscan2
- MAGEB6B | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs746213706; called by muse, mutect2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1159257962; called by mutect2, pindel
- MAGEL2 | c.3656C>T p.A1219V | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs773964986, COSV58568628; called by muse, mutect2, varscan2
- MAGEL2 | c.290del p.G97Afs*12 | Frame Shift Del (DEL) | VAF 44/163 reads (27%) | catalogued as rs1401986830; called by mutect2, pindel, varscan2
- MAP10 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV69364597; called by muse, mutect2, varscan2
- MAP3K11 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs777957821; called by muse, mutect2, varscan2
- MAP3K9 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101173401; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3789G>T p.E1263D | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.907); catalogued as rs1486662509; called by muse, mutect2, varscan2
- MBD1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 130/443 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.208); catalogued as rs768733963; called by muse, mutect2, varscan2
- MDH2 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59883841; called by muse, mutect2, varscan2
- MECOM | c.784G>T p.A262S (on ENST00000468789 / NM_001105078.4; = p.A450S on NM_004991.4) | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.239); catalogued as COSV52973954; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEGF10 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs781179892; called by muse, mutect2, varscan2
- MEGF9 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV64235073; called by mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs762448666; called by mutect2, pindel
- MRPL13 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 20/155 reads (13%) | catalogued as rs757521875, COSV60367150; called by muse, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs761538540; called by mutect2, varscan2
- MUC2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated, low confidence (0.3); catalogued as rs368249191; called by muse, mutect2, varscan2
- MUC5B | c.14047A>G p.T4683A | Missense Mutation (SNP) | VAF 139/572 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs772042519; called by muse, mutect2, varscan2
- MX1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs375670151; called by muse, mutect2, varscan2
- MXRA5 | c.6238C>T p.R2080C | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369845818, COSV99476140; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 36/152 reads (24%) | catalogued as rs764857791; called by mutect2, varscan2
- MYF5 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 95/422 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99953342; called by muse, mutect2, varscan2
- MYH7B | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306269965; called by muse, mutect2, varscan2
- MYO3B | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs940270422, COSV100509213; called by muse, mutect2, varscan2
- MYO5A | c.3043C>T p.R1015* | Nonsense Mutation (SNP) | VAF 108/378 reads (29%) | catalogued as COSV62560681; called by muse, mutect2, varscan2
- MYO7B | c.5648C>T p.T1883M | Missense Mutation (SNP) | VAF 153/319 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs372610752; called by muse, mutect2, varscan2
- MYOT | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1304612966, COSV53514863; called by muse, mutect2, varscan2
- MYOZ1 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV63772276; called by muse, mutect2
- MYPN | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 73/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172083148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYPN | c.3743C>T p.A1248V | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62734008; called by muse, mutect2
- MYT1L | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 162/343 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (1); catalogued as rs781602277, COSV67715642; called by muse, mutect2, varscan2
- NAPEPLD | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs757595572; called by muse, mutect2, varscan2
- NAV2 | c.4871C>A p.S1624* (on ENST00000396087 / NM_001244963.2; = p.S1601* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as COSV60664176; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 67/164 reads (41%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NEFM | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 160/487 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs949862142, COSV55331632, COSV55335031; called by muse, mutect2, varscan2
- NEMF | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53589871, COSV53591216; called by muse, mutect2, varscan2
- NIBAN2 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757157689; called by muse, mutect2, varscan2
- NLRP2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 125/436 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753846462; called by muse, mutect2, varscan2
- NMNAT1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs368062092, CM127763, COSV65882130; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NMNAT2 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54268591; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 42/141 reads (30%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOTCH4 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1382129029, COSV66681178; called by muse, mutect2, varscan2
- NR0B1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV66764329; called by muse, mutect2
- NR3C1 | c.2236A>G p.S746G | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99196330; called by muse, mutect2, varscan2
- NSMAF | c.1281-4G>A | Splice Region (SNP) | VAF 28/80 reads (35%) | catalogued as rs112410678; called by muse, mutect2, varscan2
- NSMF | c.1562C>T p.S521L (on ENST00000371475 / NM_001130969.3; = p.S519L on NM_015537.4) | Missense Mutation (SNP) | VAF 108/452 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs761517745; called by muse, mutect2, varscan2
- NUDCD1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs867850829, COSV53454423; called by muse, mutect2, varscan2
- NUP214 | c.6013G>A p.G2005S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63913606; called by muse, mutect2, varscan2
- OBSL1 | c.5444del p.P1815Lfs*16 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as rs748594277, COSV54705399; called by mutect2, pindel, varscan2
- OLFML2A | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773604947; called by muse, mutect2, varscan2
- OLIG2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs777954282; called by muse, mutect2, varscan2
- OLR1 | c.69del p.A24Lfs*19 | Frame Shift Del (DEL) | VAF 31/200 reads (16%) | catalogued as rs747703868; called by mutect2, pindel, varscan2
- OPN4 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779708876, COSV54116660; called by muse, mutect2, varscan2
- OR11H2 | c.284del p.N95Tfs*25 (on ENST00000556246; = p.N106Tfs*25 on NM_001197287.1) | Frame Shift Del (DEL) | VAF 46/239 reads (19%) | catalogued as rs759069772; called by mutect2, varscan2
- OR5T1 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs953752198; called by muse, mutect2, varscan2
- OSBPL2 | c.476C>T p.T159M (on ENST00000313733 / NM_144498.4; = p.T147M on NM_014835.4) | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100569134; called by muse, mutect2, varscan2
- OTOF | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 177/434 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs147435768; called by muse, mutect2, varscan2
- OTOP1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs553397205, COSV56390800; called by muse, mutect2, varscan2
- PABPC4L | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 83/324 reads (26%) | catalogued as COSV69928983; called by muse, mutect2, varscan2
- PADI4 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); catalogued as rs200925491; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 53/333 reads (16%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDHA11 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as COSV56538962; called by muse, mutect2, varscan2
- PCDHA12 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 100/463 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56531222; called by muse, mutect2, varscan2
- PCDHA3 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 26/727 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs782202213, COSV63542934; called by muse, mutect2
- PCDHGA1 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV65296778; called by muse, mutect2, varscan2
- PCDHGA2 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 121/413 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.048); catalogued as COSV99549912; called by muse, mutect2, varscan2
- PCDHGA5 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs1234948467, COSV54017918; called by muse, mutect2, varscan2
- PCDHGA6 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as rs774690686; called by muse, mutect2, varscan2
- PCLO | c.14827G>C p.V4943L | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.243); catalogued as rs558167699; called by muse, mutect2, varscan2
- PCNX2 | c.5665G>T p.G1889* | Nonsense Mutation (SNP) | VAF 45/296 reads (15%) | catalogued as COSV99269264; called by muse, mutect2, varscan2
- PCNX4 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58308762; called by muse, mutect2
- PCSK9 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1354172136; called by muse, mutect2, varscan2
- PDCL3 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs771734941, COSV51808582; called by muse, mutect2, varscan2
- PDIA2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs201324374; called by muse, mutect2, varscan2
- PDZRN3 | c.3139G>A p.G1047S | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396716270, COSV55204964; called by muse, mutect2, varscan2
- PHIP | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs747676400, COSV51502314, COSV51502965; called by muse, mutect2, varscan2
- PIGQ | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs149108761, COSV99215901; called by muse, mutect2
- PIKFYVE | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1439517036; called by muse, mutect2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 50/277 reads (18%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHG4B | c.2330del p.P777Rfs*30 (on ENST00000283426; = p.P1133Rfs*30 on NM_052909.5) | Frame Shift Del (DEL) | VAF 68/274 reads (25%) | catalogued as rs746346365, COSV52056100; called by mutect2, pindel, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs782076287; called by mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PMM2 | c.254A>G p.Q85R | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV51633578; called by muse, mutect2, varscan2
- PNPLA2 | c.798del p.A267Pfs*53 | Frame Shift Del (DEL) | VAF 78/291 reads (27%) | catalogued as CM108998; called by mutect2, pindel, varscan2
- PODN | c.1417G>A p.A473T (on ENST00000395871; = p.A425T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs760137727; called by muse, mutect2, varscan2
- PODN | c.1751C>T p.A584V (on ENST00000395871; = p.A536V on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1415501705, COSV57014428; called by muse, mutect2, varscan2
- PPP2R5E | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61742806; called by muse, mutect2, varscan2
- PPP6R2 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | catalogued as rs1415265385; called by muse, mutect2, varscan2
- PRB1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs772365043; called by muse, varscan2
- PRELP | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1220966063, COSV58114954; called by muse, mutect2
- PRKD1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1160777726, COSV59562884, COSV59575810; called by muse, mutect2, varscan2
- PRM2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs751084554; called by muse, mutect2, varscan2
- PRRC2C | c.3857G>A p.G1286D (on ENST00000367742; = p.G1284D on NM_015172.4) | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV58913823; called by muse, mutect2, varscan2
- PRSS45P | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs1278285906; called by muse, mutect2, varscan2
- PTBP3 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as COSV57584002; called by muse, mutect2, varscan2
- PTEN | c.68T>G p.L23* | Nonsense Mutation (SNP) | VAF 307/477 reads (64%) | catalogued as CM033664, CM971268, COSV64297351, COSV64303562, COSV99057990; called by muse, mutect2, varscan2
- PTF1A | c.154T>A p.F52I | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100919570; called by muse, mutect2, varscan2
- PTHLH | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52366502; called by muse, mutect2, varscan2
- PTPN14 | c.3314G>A p.S1105N | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV65283211; called by muse, mutect2, varscan2
- PTPRH | c.2347_2349del p.K783del | In Frame Del (DEL) | VAF 48/270 reads (18%) | catalogued as rs769815403; called by pindel, varscan2
- PTPRQ | c.2497del p.Q833Kfs*18 (on ENST00000616559; = p.Q791Kfs*18 on NM_001145026.2) | Frame Shift Del (DEL) | VAF 16/184 reads (9%) | catalogued as rs935928481, COSV57034264; called by mutect2, pindel
- PTPRR | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 68/310 reads (22%) | catalogued as rs759199893; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs745353960; called by mutect2, pindel
- RAPGEF6 | c.1918del p.S640Vfs*59 | Frame Shift Del (DEL) | VAF 59/236 reads (25%) | catalogued as rs752725730; called by mutect2, varscan2
- RDH14 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 119/527 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748496321; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 61/335 reads (18%) | catalogued as rs762949421; called by mutect2, varscan2
- RIC1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs760589115; called by muse, mutect2, varscan2
- RLF | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs545236290; called by muse, mutect2, varscan2
- RNF133 | c.833dup p.H279Pfs*6 | Frame Shift Ins (INS) | VAF 54/240 reads (23%) | catalogued as rs766371607; called by mutect2, varscan2
- RNF185 | c.57del p.S21Vfs*133 | Frame Shift Del (DEL) | VAF 45/169 reads (27%) | catalogued as COSV99067066; called by mutect2, pindel, varscan2
- RNF225 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs917230132; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 88/196 reads (45%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNMT | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748346138; called by muse, mutect2, varscan2
- ROBO2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as rs370653640; called by muse, mutect2, varscan2
- ROR2 | c.1230del p.S411Afs*34 | Frame Shift Del (DEL) | VAF 65/552 reads (12%) | catalogued as COSV100996158; called by mutect2, pindel, varscan2
- RP1L1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776560263, COSV61446208; called by muse, mutect2, varscan2
- RPGRIP1L | c.2119del p.S707Afs*10 | Frame Shift Del (DEL) | VAF 23/179 reads (13%) | catalogued as rs1567840180; called by mutect2, pindel, varscan2
- RPRD2 | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.081); catalogued as rs782537905; called by muse, varscan2
- RPTOR | c.3104C>T p.T1035M | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs776174012, COSV60802560; called by muse, mutect2, varscan2
- RSPH4A | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 82/412 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs1330301417; called by muse, mutect2, varscan2
- SAMHD1 | c.1682del p.K561Rfs*35 (on ENST00000262878 / NM_001363729.2; = p.K596Rfs*35 on NM_015474.4) | Frame Shift Del (DEL) | VAF 124/391 reads (32%) | catalogued as rs1215993198; called by mutect2, varscan2
- SAP130 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52097278; called by muse, mutect2, varscan2
- SASH1 | c.3284C>T p.T1095M | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs547938889, COSV100820874; called by muse, mutect2, varscan2
- SCAF4 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 22/134 reads (16%) | catalogued as rs924159079, COSV54586260; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 44/188 reads (23%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCARF2 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs1166105255; called by muse, mutect2, varscan2
- SCART1 | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs754370337; called by muse, mutect2, varscan2
- SCPEP1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs771883135, COSV51854990; called by muse, varscan2
- SENP7 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV100053957; called by muse, mutect2, varscan2
- SERPINA1 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100872053; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 31/176 reads (18%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SETX | c.6859C>T p.R2287* | Nonsense Mutation (SNP) | VAF 85/340 reads (25%) | catalogued as rs1339011741, CM111221, COSV56384112; called by muse, varscan2
- SGCD | c.268G>A p.A90T (on ENST00000435422 / NM_001128209.2; = p.A91T on NM_000337.5) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as rs768114319; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 39/188 reads (21%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH2D3A | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1420756723; called by muse, mutect2, varscan2
- SH3YL1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545313794; called by muse, mutect2, varscan2
- SIAE | c.68-3del | Splice Region (DEL) | VAF 92/372 reads (25%) | catalogued as rs746169895; called by mutect2, pindel, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 38/157 reads (24%) | catalogued as rs1567251966; called by mutect2, varscan2
- SIT1 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99425790; called by muse, mutect2, varscan2
- SLC30A1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 18/293 reads (6%) | catalogued as COSV100879120; called by muse, mutect2
- SLC35E1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs768784190; called by muse, mutect2
- SLC38A1 | c.788C>A p.T263K | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.049); catalogued as rs369551715; called by muse, mutect2, varscan2
- SLC66A3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 88/426 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754776013, COSV54468062; called by muse, mutect2, varscan2
- SLC9A5 | c.1165T>C p.F389L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV55362499; called by muse, mutect2, varscan2
- SLIT3 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375040794; called by muse, mutect2, varscan2
- SLK | c.3428G>A p.R1143H | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539493701; called by muse, mutect2, varscan2
- SMAD9 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1453268397, COSV100615041; called by muse, mutect2, varscan2
- SMS | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 103/379 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65115474; called by muse, mutect2, varscan2
- SNAP91 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as rs1025531569; called by muse, mutect2
- SORCS1 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 150/239 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs201674495, COSV53840707; called by muse, mutect2, varscan2
- SP1 | c.1658C>T p.A553V (on ENST00000327443 / NM_138473.3; = p.A546V on NM_003109.1) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1248159161; called by muse, mutect2, varscan2
- SP1 | c.1997G>A p.R666H (on ENST00000327443 / NM_138473.3; = p.R659H on NM_003109.1) | Missense Mutation (SNP) | VAF 98/439 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100540600; called by muse, mutect2, varscan2
- SP9 | c.1404_1409del p.A469_A470del | In Frame Del (DEL) | VAF 4/50 reads (8%) | catalogued as rs746223726; called by mutect2, varscan2*
- SPEG | c.8099C>T p.P2700L | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs933038018, COSV56666936; called by muse, mutect2
- SPHK2 | c.872+1del | Frame Shift Del (DEL) | VAF 33/129 reads (26%) | catalogued as rs748435598; called by mutect2, pindel, varscan2
- SPTBN4 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs377199238; called by muse, mutect2, varscan2
- SRRM2 | c.7332G>T p.Q2444H | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1328336738; called by muse, mutect2
- STAB1 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781466503; called by muse, mutect2, varscan2
- STAT2 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs780130229, COSV58475754; called by muse, mutect2, varscan2
- STK36 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 112/503 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1476330338; called by muse, mutect2, varscan2
- STRAP | c.444del p.A149Lfs*26 | Frame Shift Del (DEL) | VAF 45/245 reads (18%) | catalogued as rs1470408003; called by mutect2, pindel, varscan2
- STX11 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 102/520 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.45); catalogued as rs766869715; called by muse, mutect2, varscan2
- STX3 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV55694937; called by muse, mutect2, varscan2
- STYK1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs537296580, COSV50012804; called by muse, mutect2, varscan2
- SVEP1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs757230444; called by muse, mutect2, varscan2
- SYNE1 | c.3850C>T p.R1284W (on ENST00000367255 / NM_182961.4; = p.R1291W on NM_033071.3) | Missense Mutation (SNP) | VAF 45/544 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs140780725; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SYNM | c.3280A>G p.T1094A | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs532656317; called by muse, mutect2, varscan2
- TAAR5 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs756342868, COSV57798988; called by muse, mutect2, varscan2
- TAF1 | c.2930G>A p.R977H (on ENST00000373790 / NM_138923.4; = p.R998H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773557452, COSV52116921; called by muse, mutect2, varscan2
- TANC2 | c.5791C>T p.R1931C | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.548); catalogued as rs759117220; called by muse, mutect2, varscan2
- TAS1R3 | c.1812del p.L606Wfs*43 | Frame Shift Del (DEL) | VAF 42/170 reads (25%) | catalogued as rs777573279, COSV100229689; called by mutect2, varscan2
- TBC1D10C | c.1281dup p.I428Hfs*26 | Frame Shift Ins (INS) | VAF 52/170 reads (31%) | catalogued as rs756043635; called by mutect2, varscan2
- TBL1X | c.689del p.G230Afs*18 | Frame Shift Del (DEL) | VAF 42/183 reads (23%) | catalogued as COSV54285007; called by mutect2, pindel, varscan2
- TCF20 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs148610859; called by muse, mutect2, varscan2
- TECPR2 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV63969931; called by muse, mutect2, varscan2
- TENM1 | c.4103C>T p.T1368I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64441698; called by muse, mutect2
- TENM4 | c.6730C>T p.R2244C | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777521844, COSV53634011; called by muse, mutect2, varscan2
- TEP1 | c.5756G>A p.R1919H | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.649); catalogued as rs772081432, COSV53001328; called by muse, mutect2, varscan2
- TERF2IP | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs767622383; called by muse, mutect2, varscan2
- TET1 | c.4832del p.N1611Tfs*13 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | catalogued as rs764225020; called by mutect2, pindel, varscan2
- TEX10 | c.467T>A p.I156N | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66516462; called by muse, mutect2, varscan2
- TEX29 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs200978073, COSV99366139; called by muse, mutect2, varscan2
- TGFBR1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564161322, CM165735, COSV66624829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGIF2LX | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 179/612 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV52215080, COSV52215374, COSV99383415; called by muse, mutect2, varscan2
- TIAM2 | c.4079C>T p.T1360M (on ENST00000529824; = p.T1331M on NM_012454.3) | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs774102649, COSV51642358; called by muse, mutect2, varscan2
- TLE2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs774132378; called by muse, mutect2, varscan2
- TM9SF4 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756498435, COSV54107654; called by muse, mutect2, varscan2
- TMEM131 | c.2444del p.N815Ifs*2 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as rs1559368991; called by mutect2, pindel, varscan2
- TMEM156 | c.205A>T p.I69F | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs548229487; called by muse, mutect2
- TMEM87B | c.52T>C p.C18R | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1478964392; called by muse, mutect2, varscan2
- TMOD4 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as rs146592769; called by muse, mutect2, varscan2
- TNFRSF25 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.745); catalogued as rs769970268; called by muse, mutect2, varscan2
- TNKS | c.2941T>C p.S981P | Missense Mutation (SNP) | VAF 105/433 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs757008221; called by muse, mutect2, varscan2
- TNRC18 | c.6058G>A p.A2020T | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768337574; called by muse, mutect2, varscan2
- TNRC18 | c.5356dup p.R1786Pfs*37 | Frame Shift Ins (INS) | VAF 61/258 reads (24%) | catalogued as rs773635373; called by mutect2, pindel, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TNRC18 | c.1505del p.P502Rfs*88 | Frame Shift Del (DEL) | VAF 87/300 reads (29%) | catalogued as rs759798146; called by mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 48/175 reads (27%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TOPBP1 | c.2801A>G p.Y934C | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV53441591; called by muse, mutect2, varscan2
- TPBG | c.468C>A p.D156E | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs775665171; called by muse, mutect2, varscan2
- TPST2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1490815963; called by muse, mutect2, varscan2
- TRAP1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs754378125, COSV55917501; called by muse, mutect2, varscan2
- TREML2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs371918667; called by muse, mutect2, varscan2
- TRH | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 83/383 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs138139186; called by muse, mutect2, varscan2
- TRIM56 | c.1525del p.R509Gfs*23 | Frame Shift Del (DEL) | VAF 69/274 reads (25%) | catalogued as COSV60157516; called by mutect2, pindel, varscan2
- TRIM71 | c.1585C>A p.L529M | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.023); catalogued as rs748172146; called by muse, mutect2, varscan2
- TRIO | c.2383G>A p.A795T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.985); catalogued as rs1460535762, COSV60088644; called by muse, mutect2
- TRIO | c.8667A>C p.E2889D | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702686; called by muse, mutect2, varscan2
- TRPM6 | c.3435dup p.L1146Tfs*3 | Frame Shift Ins (INS) | VAF 60/232 reads (26%) | catalogued as rs1564006687; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TRPS1 | c.23del p.P8Lfs*2 (on ENST00000220888 / NM_001330599.2; = p.P21Lfs*2 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 45/235 reads (19%) | catalogued as COSV55232559; called by mutect2, pindel, varscan2
- TTBK1 | c.1899del p.T634Rfs*39 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV52491793; called by mutect2, pindel, varscan2
- TTC13 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs748928691, COSV100793056, COSV64170275; called by muse, mutect2, varscan2
- TTC28 | c.4351G>A p.G1451S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767044155; called by muse, mutect2, varscan2
- TTF1 | c.1007del p.K336Rfs*87 | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | catalogued as rs772401251; called by mutect2, varscan2
- TTLL5 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as rs771955076; called by muse, mutect2, varscan2
- TTN | c.72979G>A p.E24327K (on ENST00000591111; = p.E16903K on NM_003319.4) | Missense Mutation (SNP) | VAF 91/463 reads (20%) | PolyPhen probably damaging (0.994); catalogued as rs756933390, COSV60153230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBXN1 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); catalogued as rs1039598952, COSV53656054; called by muse, mutect2, varscan2
- USF1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1319142378, COSV99230831; called by muse, mutect2, varscan2
- USP28 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV50190086; called by muse, varscan2
- USP51 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1323101459; called by muse, mutect2, varscan2
- UTP14C | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382314037; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | catalogued as rs761528888; called by mutect2, varscan2
- VCAN | c.9584G>A p.R3195Q | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145625752; called by muse, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 32/192 reads (17%) | catalogued as rs748321397; called by mutect2, varscan2
- VPS35L | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs1375262931; called by muse, mutect2, varscan2
- VTN | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs782601763; called by muse, mutect2, varscan2
- VWA2 | c.1892G>A p.G631D | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162802846; called by muse, mutect2, varscan2
- VWA3A | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs758832147, COSV67011343; called by muse, mutect2, varscan2
- VWC2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1338399084, COSV61484792; called by muse, mutect2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, varscan2
- XPO5 | c.1529del p.L510Wfs*12 | Frame Shift Del (DEL) | VAF 44/256 reads (17%) | catalogued as rs756386937; called by pindel, varscan2
- XYLT1 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs748655641, COSV99077145; called by muse, mutect2, varscan2
- ZBED1 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs141579040; called by muse, mutect2, varscan2
- ZBTB7A | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs777079528, COSV59327434; called by muse, mutect2, varscan2
- ZC3H12C | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.403); catalogued as COSV53712018; called by muse, mutect2, varscan2
- ZC3H18 | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 58/210 reads (28%) | catalogued as rs778351069, COSV56327837; called by muse, mutect2, varscan2
- ZFAND3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1485524977; called by muse, mutect2, varscan2
- ZFHX3 | c.5677A>G p.R1893G | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1465596056; called by muse, mutect2, varscan2
- ZFHX4 | c.6014del p.P2005Rfs*21 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | catalogued as COSV50481316; called by pindel, varscan2
- ZFHX4 | c.6310G>A p.A2104T | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs748293539, COSV51479738; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 61/175 reads (35%) | catalogued as COSV60156851; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.178); catalogued as rs182377695; called by muse, mutect2, varscan2
- ZMYND8 | c.1904del p.K635Sfs*14 (on ENST00000311275 / NM_001363741.2; = p.K655Sfs*14 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/320 reads (26%) | catalogued as rs776813452; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 70/259 reads (27%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF133 | c.1315G>A p.V439I (on ENST00000316358 / NM_001352454.2; = p.V438I on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs148666002; called by muse, mutect2, varscan2
- ZNF148 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100641995; called by muse, mutect2
- ZNF275 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs782039047; called by muse, mutect2, varscan2
- ZNF281 | c.275del p.P92Lfs*7 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as rs751889036; called by mutect2, varscan2
- ZNF337 | c.1705del p.E569Kfs*15 | Frame Shift Del (DEL) | VAF 33/218 reads (15%) | catalogued as COSV53321245; called by mutect2, pindel, varscan2
- ZNF485 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as rs368421127; called by muse, mutect2, varscan2
- ZNF570 | c.1516dup p.T506Nfs*37 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | catalogued as rs1203012118; called by mutect2, varscan2
- ZNF579 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as rs1356850195, COSV57638519; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 64/212 reads (30%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs750329558; called by mutect2, varscan2
- ZNF831 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs927913494, COSV100926022; called by muse, mutect2, varscan2
- ZNF875 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs552933332, COSV100183357; called by muse, mutect2, varscan2
- A3GALT2 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA9 | c.2984T>A p.L995H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG5 | c.1900C>A p.L634I | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ACTL9 | c.914del p.P305Qfs*? | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | called by mutect2, pindel, varscan2
- ACTN4 | c.2635T>C p.C879R | Missense Mutation (SNP) | VAF 106/418 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADA | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 142/554 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS18 | c.3611G>A p.C1204Y | Missense Mutation (SNP) | VAF 42/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB2 | c.1649G>A p.G550D | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF3 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRG4 | c.4106C>T p.A1369V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- ADNP2 | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.046); called by muse, mutect2
- ADNP2 | c.2768del p.T923Rfs*4 | Frame Shift Del (DEL) | VAF 59/241 reads (24%) | called by mutect2, pindel, varscan2
- ADRA2A | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, varscan2
- AFAP1 | c.970del p.I324Sfs*31 | Frame Shift Del (DEL) | VAF 41/237 reads (17%) | called by mutect2, pindel, varscan2
- AGFG1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AHCYL2 | c.751del p.A251Pfs*21 | Frame Shift Del (DEL) | VAF 32/158 reads (20%) | called by mutect2, pindel, varscan2
- AHRR | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKAP17A | c.244del p.E82Rfs*29 | Frame Shift Del (DEL) | VAF 107/434 reads (25%) | called by mutect2, pindel, varscan2
- AKR7A3 | c.962dup p.L321Ffs*25 | Frame Shift Ins (INS) | VAF 85/461 reads (18%) | called by mutect2, pindel, varscan2
- AL355102.2 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.275); called by muse, varscan2
- ALDH1A1 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2
- ALOX15 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMER2 | c.327dup p.A110Cfs*153 | Frame Shift Ins (INS) | VAF 34/110 reads (31%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.3308_3309dup p.D1104Kfs*215 | Frame Shift Ins (INS) | VAF 76/622 reads (12%) | called by mutect2, varscan2
- ANP32B | c.258del p.K86Nfs*8 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | called by mutect2, pindel, varscan2
- APBB1IP | c.1601C>T p.T534M | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APH1B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2
- ARHGAP17 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP25 | c.212G>T p.R71M (on ENST00000409202 / NM_001007231.3; = p.R64M on NM_014882.3) | Missense Mutation (SNP) | VAF 19/491 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- ARHGAP25 | c.1121C>T p.A374V (on ENST00000409202 / NM_001007231.3; = p.A366V on NM_014882.3) | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP44 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 68/304 reads (22%) | called by mutect2, pindel, varscan2
- ARID4A | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARMC8 | c.1958G>T p.S653I (on ENST00000469044 / NM_001363941.2; = p.S639I on NM_015396.6) | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ATAT1 | c.899del p.P300Hfs*31 (on ENST00000376485; = p.P300Hfs*65 on NM_024909.4) | Frame Shift Del (DEL) | VAF 49/260 reads (19%) | called by mutect2, pindel, varscan2
- ATF6B | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- ATN1 | c.3538A>G p.S1180G | Missense Mutation (SNP) | VAF 72/370 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATP2B3 | c.1983G>A p.W661* | Nonsense Mutation (SNP) | VAF 42/147 reads (29%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.288+5G>A | Splice Region (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- ATP6V1H | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, varscan2
- ATXN2 | c.1948G>A p.V650I (on ENST00000550104; = p.V490I on NM_002973.4) | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- AUTS2 | c.1228A>G p.S410G | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BAAT | c.1del p.M1? | Frame Shift Del (DEL) | VAF 73/292 reads (25%) | called by mutect2, varscan2
- BAHCC1 | c.1676dup p.I560Hfs*4 | Frame Shift Ins (INS) | VAF 24/148 reads (16%) | called by mutect2, pindel, varscan2
- BAK1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 29/379 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BANP | c.1081C>T p.Q361* (on ENST00000286122; = p.Q330* on NM_017869.4) | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- BCL11B | c.1916C>T p.A639V (on ENST00000357195 / NM_001282237.2; = p.A568V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.041); called by muse, mutect2
- BCL7C | c.273T>A p.D91E | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- BCO1 | c.1580del p.K527Sfs*20 | Frame Shift Del (DEL) | VAF 78/361 reads (22%) | called by mutect2, pindel, varscan2
- BICD1 | c.1794del p.T599Qfs*25 | Frame Shift Del (DEL) | VAF 101/465 reads (22%) | called by mutect2, pindel, varscan2
- BICRA | c.3386A>G p.D1129G | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- BMF | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, varscan2
- BPIFC | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BRCC3 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 59/191 reads (31%) | called by muse, mutect2, varscan2
- BRPF1 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BTBD7 | c.2303del p.P768Qfs*53 | Frame Shift Del (DEL) | VAF 44/160 reads (28%) | called by mutect2, pindel
- C18orf63 | c.1018del p.M340Cfs*6 | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | called by mutect2, pindel, varscan2
- C1GALT1C1L | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- C1QA | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QC | c.395del p.P132Lfs*6 | Frame Shift Del (DEL) | VAF 101/429 reads (24%) | called by mutect2, pindel, varscan2
- C6orf118 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CABIN1 | c.5644G>T p.E1882* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | called by muse, mutect2, varscan2
- CACNA1E | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, varscan2
- CARD9 | c.1024C>A p.R342S | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, varscan2
- CARMIL2 | c.1616_1617del p.L539Rfs*52 | Frame Shift Del (DEL) | VAF 56/285 reads (20%) | called by mutect2, pindel, varscan2
- CAVIN2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCAR2 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCDC146 | c.2853G>T p.K951N | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC168 | c.7706dup p.N2569Kfs*26 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, varscan2
- CCDC54 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCDC77 | c.19C>T p.H7Y | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNF | c.1588-1G>T p.X530_splice | Splice Site (SNP) | VAF 71/196 reads (36%) | called by muse, mutect2, varscan2
- CCSAP | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- CCT8 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CD109 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD163L1 | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CD300LF | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CD44 | c.1963G>T p.A655S | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CDK8 | c.78dup p.V27Sfs*20 | Frame Shift Ins (INS) | VAF 38/230 reads (17%) | called by mutect2, pindel, varscan2
- CELF2 | c.1523A>C p.Y508S (on ENST00000416382 / NM_001025077.3; = p.Y521S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CELF3 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CELF4 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR1 | c.3691del p.V1231Wfs*28 | Frame Shift Del (DEL) | VAF 91/408 reads (22%) | called by mutect2, pindel, varscan2
- CEP290 | c.3235del p.M1079Cfs*9 | Frame Shift Del (DEL) | VAF 51/261 reads (20%) | called by mutect2, varscan2
- CFAP100 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 78/312 reads (25%) | called by muse, mutect2, varscan2
- CFAP54 | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CFAP73 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 97/417 reads (23%) | called by mutect2, pindel, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, varscan2
- CHM | c.984del p.K328Nfs*2 | Frame Shift Del (DEL) | VAF 64/236 reads (27%) | called by mutect2, pindel, varscan2
- CHMP4B | c.67del p.Q23Rfs*14 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | called by mutect2, pindel, varscan2
- CHST1 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CILP | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIT | c.3634dup p.M1212Nfs*13 | Frame Shift Ins (INS) | VAF 37/179 reads (21%) | called by mutect2, pindel, varscan2
- CLSTN1 | c.2703G>A p.M901I (on ENST00000377298 / NM_001009566.3; = p.M891I on NM_014944.4) | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- COA1 | c.62del p.F21Sfs*69 | Frame Shift Del (DEL) | VAF 45/218 reads (21%) | called by mutect2, pindel, varscan2
- COA8 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- COIL | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 110/405 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- COL24A1 | c.223del p.V75Sfs*3 | Frame Shift Del (DEL) | VAF 57/237 reads (24%) | called by mutect2, pindel, varscan2
- COL3A1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- COMMD3 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- COPB1 | c.1751A>C p.E584A | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CPNE6 | c.243dup p.E82* | Frame Shift Ins (INS) | VAF 47/190 reads (25%) | called by mutect2, varscan2
- CRB2 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CREB3L4 | c.427T>A p.W143R | Missense Mutation (SNP) | VAF 122/669 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by mutect2, varscan2
- CRISP3 | c.638A>G p.Y213C (on ENST00000371159 / NM_001368123.1; = p.Y195C on NM_006061.4) | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CRYBG1 | c.4008del p.E1337Rfs*26 | Frame Shift Del (DEL) | VAF 45/221 reads (20%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSF2RB | c.334T>G p.S112A | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSGALNACT2 | c.993dup p.H332Sfs*10 | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- CTNNAL1 | c.1996C>A p.L666I | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CUL9 | c.7071G>T p.Q2357H | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CWH43 | c.1446G>A p.W482* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | called by muse, varscan2
- CXCL5 | c.343T>C p.*115Rext*23 | Nonstop Mutation (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- DDC | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 158/626 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DDX21 | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- DDX31 | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX51 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDX59 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- DENND1A | c.1797del p.D601Tfs*2 | Frame Shift Del (DEL) | VAF 19/157 reads (12%) | called by mutect2, pindel, varscan2
- DENND6B | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DFFB | c.900del p.K300Nfs*2 | Frame Shift Del (DEL) | VAF 101/389 reads (26%) | called by mutect2, pindel, varscan2
- DGCR2 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DGKK | c.573_574dup p.G192Efs*3 | Frame Shift Ins (INS) | VAF 30/108 reads (28%) | called by mutect2, varscan2
- DHDH | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX34 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX38 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DIAPH1 | c.2030del p.P677Hfs*91 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- DIP2A | c.2163G>T p.Q721H | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLST | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMXL2 | c.5035G>A p.V1679M | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DMXL2 | c.950del p.N317Ifs*2 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | called by mutect2, pindel
- DNAH11 | c.10354G>T p.G3452C | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2
- DNAH3 | c.5029A>G p.N1677D | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DNAH5 | c.7453G>A p.V2485M | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- DNAJA1 | c.276del p.F92Lfs*22 | Frame Shift Del (DEL) | VAF 28/304 reads (9%) | called by mutect2, pindel
- DNMT1 | c.3199G>T p.D1067Y | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DOCK11 | c.920T>G p.L307W | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DOP1A | c.7097del p.N2366Ifs*69 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- DRAM2 | c.690del p.Q231Rfs*14 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | called by mutect2, pindel, varscan2
- DSG1 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DST | c.10242del p.L3415* | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- DST | c.5435G>C p.S1812T | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DSTN | c.46del p.Y16Mfs*3 | Frame Shift Del (DEL) | VAF 33/104 reads (32%) | called by mutect2, varscan2
- DTX1 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DUS3L | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DUSP28 | c.65T>G p.V22G | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, varscan2
- DUSP28 | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- DUSP29 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DZIP1 | c.2132G>A p.S711N (on ENST00000347108; = p.S692N on NM_014934.5) | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- E2F3 | c.529dup p.T177Nfs*4 | Frame Shift Ins (INS) | VAF 38/207 reads (18%) | called by mutect2, pindel, varscan2
- EDEM3 | c.1781_1783del p.K594del | In Frame Del (DEL) | VAF 52/250 reads (21%) | called by pindel, varscan2
- EFR3B | c.984G>T p.V328= | Splice Region (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- EGR4 | c.1454G>A p.C485Y (on ENST00000545030; = p.C382Y on NM_001965.4) | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- EIF4A1 | c.990C>A p.D330E | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EIF4H | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- ELFN1 | c.788del p.P263Hfs*97 | Frame Shift Del (DEL) | VAF 62/230 reads (27%) | called by mutect2, pindel, varscan2
- ENPP5 | c.1300T>A p.F434I | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, varscan2
- EPC1 | c.677dup p.N226Kfs*2 | Frame Shift Ins (INS) | VAF 47/242 reads (19%) | called by pindel, varscan2
- ERAP1 | c.2739A>T p.E913D | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- ESRRB | c.453dup p.R152Afs*25 | Frame Shift Ins (INS) | VAF 92/430 reads (21%) | called by mutect2, pindel, varscan2
- ESYT3 | c.2174T>C p.M725T | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ETAA1 | c.1653del p.F551Lfs*6 | Frame Shift Del (DEL) | VAF 31/148 reads (21%) | called by mutect2, pindel, varscan2
- ETFA | c.1000T>A p.*334Rext*6 | Nonstop Mutation (SNP) | VAF 45/190 reads (24%) | called by muse, mutect2, varscan2
- EXOC1 | c.2447A>T p.Y816F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EXOSC10 | c.2650C>T p.Q884* (on ENST00000376936 / NM_001001998.3; = p.Q859* on NM_002685.4) | Nonsense Mutation (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- F9 | c.556dup p.T186Nfs*3 | Frame Shift Ins (INS) | VAF 34/234 reads (15%) | called by mutect2, pindel, varscan2
- FAM114A1 | c.998del p.N333Mfs*3 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by mutect2, pindel, varscan2
- FAM151A | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 77/344 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47B | c.1908_1910del p.E636del | In Frame Del (DEL) | VAF 11/37 reads (30%) | called by pindel, varscan2
- FAM53C | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- FASN | c.4057del p.L1353Sfs*20 | Frame Shift Del (DEL) | VAF 96/412 reads (23%) | called by mutect2, pindel, varscan2
- FBXO42 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- FEM1B | c.1602T>A p.S534R | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2
- FGD2 | c.938T>G p.I313R | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FGD4 | c.1119_1121del p.W373_N374delinsC | In Frame Del (DEL) | VAF 63/362 reads (17%) | called by mutect2, pindel, varscan2
- FIGN | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 160/387 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIGNL2 | c.1079C>A p.A360D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- FIP1L1 | c.909A>T p.E303D | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.92A>T p.D31V | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- FMR1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXP1 | c.447del p.K149Nfs*57 | Frame Shift Del (DEL) | VAF 111/419 reads (26%) | called by mutect2, pindel, varscan2
- FSCB | c.753del p.V252Wfs*6 | Frame Shift Del (DEL) | VAF 81/274 reads (30%) | called by mutect2, pindel, varscan2
- FTO | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FUNDC1 | c.312del p.D105Mfs*2 | Frame Shift Del (DEL) | VAF 33/153 reads (22%) | called by mutect2, pindel, varscan2
- FUT8 | c.1207del p.R403Efs*12 (on ENST00000360689 / NM_001371534.1; = p.R240Efs*12 on NM_004480.4) | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | called by pindel, varscan2
- FYB1 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD10 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZR1 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA2 | c.1295T>A p.F432Y | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GABRG2 | c.1235del p.K412Rfs*20 (on ENST00000361925 / NM_001375343.1; = p.K372Rfs*20 on NM_000816.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 97/382 reads (25%) | called by mutect2, pindel, varscan2
- GAD1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 24/451 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2
- GALNT12 | c.286_288del p.E96del | In Frame Del (DEL) | VAF 22/66 reads (33%) | called by pindel, varscan2
- GASK1B | c.524T>A p.I175N | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF5 | c.157del p.L53Wfs*34 | Frame Shift Del (DEL) | VAF 45/198 reads (23%) | called by mutect2, pindel, varscan2
- GDPD5 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GFPT2 | c.777_779del p.F260del | In Frame Del (DEL) | VAF 27/121 reads (22%) | called by pindel, varscan2
- GFRA1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 81/464 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GFUS | c.599-4G>A | Splice Region (SNP) | VAF 52/238 reads (22%) | called by muse, mutect2, varscan2
- GGN | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GINS4 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GJA1 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 65/340 reads (19%) | called by muse, mutect2, varscan2
- GLDC | c.2784G>T p.Q928H | Missense Mutation (SNP) | VAF 135/428 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GLI1 | c.2932del p.A978Qfs*42 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- GNG12 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- GNL2 | c.874G>T p.G292* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- GOLGA3 | c.3215C>T p.T1072I | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA3 | c.3051G>T p.K1017N | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- GPAM | c.1668dup p.I557Yfs*48 | Frame Shift Ins (INS) | VAF 64/361 reads (18%) | called by mutect2, pindel, varscan2
- GPATCH1 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH2 | c.990del p.M333Cfs*74 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | called by pindel, varscan2
- GPNMB | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- GREB1 | c.5500G>A p.D1834N | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, varscan2
- GRINA | c.333del p.N112Tfs*56 | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | called by mutect2, pindel, varscan2
- GRM6 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C1 | c.4962del p.G1655Afs*21 | Frame Shift Del (DEL) | VAF 60/246 reads (24%) | called by pindel, varscan2
- GZMK | c.629del p.C210Lfs*9 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel
- HACE1 | c.2396del p.N799Ifs*22 | Frame Shift Del (DEL) | VAF 70/342 reads (20%) | called by mutect2, pindel, varscan2
- HDGFL1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, varscan2
- HECTD4 | c.10114G>A p.G3372R | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD4 | c.7189C>T p.R2397W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELZ2 | c.3139G>A p.A1047T (on ENST00000467148 / NM_001037335.2; = p.A478T on NM_033405.3) | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HEXB | c.956_957del p.F319Wfs*22 | Frame Shift Del (DEL) | VAF 37/228 reads (16%) | called by mutect2, pindel, varscan2
- HMX3 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- HNF1B | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HNRNPUL2 | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA4L | c.2075A>T p.Y692F | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- HSPA8 | c.332C>A p.T111N | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPA9 | c.1142_1144del p.G381del | In Frame Del (DEL) | VAF 99/385 reads (26%) | called by mutect2, pindel, varscan2
- HSPA9 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- HSPBP1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICE1 | c.978del p.F326Lfs*82 | Frame Shift Del (DEL) | VAF 64/246 reads (26%) | called by mutect2, pindel, varscan2
- IDH2 | c.1329C>A p.S443R | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGDCC3 | c.920G>A p.C307Y | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- IGDCC4 | c.3287del p.P1096Lfs*18 | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- IGF2R | c.690del p.G231Afs*7 | Frame Shift Del (DEL) | VAF 56/271 reads (21%) | called by mutect2, pindel, varscan2
- IGFN1 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.538); called by muse, varscan2
- IGHD | c.1143del p.L382* | Frame Shift Del (DEL) | VAF 58/225 reads (26%) | called by mutect2, pindel, varscan2
- IGSF1 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGSF9 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- INO80B | c.643A>G p.K215E | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
869 further variants in this file (377 protein-altering or splice-affecting, 287 silent, 205 other) are not listed here.
